Gene-level copy-number profile of tumor specimen C3L-09966-01 from CPTAC case C3L-09966, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 85.2 years (31,122 days).
Specimen C3L-09966-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 69327aba-989e-4f79-8c35-c4811c676f47.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09966-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/74d534a5-5b0f-4c60-b9fe-12b6c41de56f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 718; copy number 2: 20,176; copy number 3: 23,961; copy number 4: 10,432; copy number 5: 1,838; copy number 6: 211; copy number 7: 600; copy number 8: 206; copy number 9: 82; copy number 10: 5; copy number 11: 78; copy number 23: 11; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,682,996–90,683,123, 1 gene (within-gene range 0–2): AC093729.1.
- chr6:162,568,379–162,569,728, 1 gene (within-gene range 0–3): KRT8P44.
- chr10:14,061–931,705, 16 genes: AC215217.1, AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B.
- chr10:73,909,177–76,560,168, 48 genes (within-gene range 0–2): PLAU, C10orf55, VCL, AL596247.1, AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 983 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:171,841,498–172,418,466, 1 gene, copy number 8 (within-gene range 5–11): DNM3.
- chr1:172,138,397–173,064,015, 16 genes, copy number 8–11 (within-gene range 4–11): DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1.
- chr2:129,825,126–129,877,664, 1 gene, copy number 7: LINC02572.
- chr2:169,694,488–170,655,171, 11 genes, copy number 8 (within-gene range 2–8): KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1.
- chr2:170,990,823–172,736,206, 29 genes, copy number 9 (within-gene range 5–9): TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2.
- chr2:176,495,255–177,559,299, 32 genes, copy number 7 (within-gene range 4–7): LINC01117, AC017048.1, AC017048.2, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS.
- chr2:184,204,372–184,939,492, 5 genes, copy number 7–9: AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33.
- chr2:186,486,253–187,556,288, 11 genes, copy number 7–10 (within-gene range 4–10): ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL.
- chr2:189,441,446–189,784,364, 12 genes, copy number 7 (within-gene range 5–7): WDR75, KDM3AP1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1.
- chr10:3,433,508–6,254,644, 67 genes, copy number 7–31 (within-gene range 4–31) (broad region; genes not listed).
- chr12:70,515,870–70,920,738, 4 genes, copy number 7 (within-gene range 4–7): PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr17:37,084,992–37,884,743, 19 genes, copy number 8 (within-gene range 8–15): ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7.
- chr17:39,461,486–40,885,242, 74 genes, copy number 7 (broad region; genes not listed).
- chr17:67,337,916–67,785,293, 14 genes, copy number 11: PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41.
- chr20:31,968,151–32,003,387, 1 gene, copy number 7 (within-gene range 3–7): XKR7.
- chr20:32,005,671–35,753,719, 138 genes, copy number 7 (broad region; genes not listed).
- chr20:42,072,752–64,327,972, 548 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 717. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
